Gene-level copy-number profile of tumor specimen ALCH-ABXY-TTP1-A from ALCHEMIST case ALCH-ABXY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.9 years (22,593 days).
Specimen ALCH-ABXY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1bcad46c-75dc-44a6-9913-6de65867ba75.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABXY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/e762cc7b-7787-4270-902c-3999d79e8dd1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 12,681; copy number 2: 41,095; copy number 3: 4,528; copy number 4: 27; copy number 5: 18; copy number 6: 1; copy number 7: 5.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,487,428–74,487,540, 1 gene (within-gene range 0–1): RNA5SP233.
- chr7:140,404,058–140,435,787, 2 genes (within-gene range 0–2): RAB19, AC069335.1.
- chr8:33,580,210–33,600,023, 2 genes: RN7SL621P, DUSP26.
- chr8:33,641,581–33,641,939, 1 gene (within-gene range 0–1): BUD31P1.
- chr9:121,494,519–121,494,821, 1 gene (within-gene range 0–2): RN7SL187P.
- chr10:119,499,817–119,542,719, 1 gene: RGS10.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr16:56,865,207–56,915,850, 3 genes (within-gene range 0–2): SLC12A3, MIR6863, RPS24P17.
- chr17:331,205–333,488, 1 gene (within-gene range 0–1): AC129507.1.
- chr22:16,521,059–16,527,237, 1 gene: AP000547.2.
- chr22:17,137,511–17,165,445, 2 genes: HDHD5, HDHD5-AS1.
- chr22:17,192,936–17,193,308, 1 gene (within-gene range 0–1): AC005300.1.
- chr22:17,777,322–17,779,481, 1 gene: LINC00528.
- chr22:18,178,038–18,345,899, 2 genes: FAM230D, GGTLC5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,738,167–136,748,525, 4 genes, copy number 7: LCN10, AL355987.1, LCN6, MIR6722.
- chr9:136,759,634–136,766,255, 1 gene, copy number 7: LCN15.
- chr12:57,869,834–58,105,935, 10 genes, copy number 5: AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr16:88,863,333–88,866,660, 1 gene, copy number 5: PABPN1L.
- chr21:17,438,821–17,612,945, 8 genes, copy number 5–6 (within-gene range 2–6): LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3.

Autosomal genes at a single copy (total copy number 1): 11,894. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
